Gene-level copy-number profile of tumor specimen TCGA-60-2703-01A from TCGA case TCGA-60-2703, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.9 years (27,003 days).
Specimen TCGA-60-2703-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.7286e0a2-9c55-4445-bfa7-3657fe1a31b8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-60-2703-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ad634357-946d-4ea3-a1e7-8efb6dffee81

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 131; copy number 1: 934; copy number 2: 23,890; copy number 3: 15,428; copy number 4: 10,201; copy number 5: 4,079; copy number 6: 3,398; copy number 7: 1,250; copy number 8: 90; copy number 10: 243; copy number 35: 175.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-60-2703-01A-11D-2041-01): tumor purity 0.26, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 123 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:186,701,579–187,517,208, 13 genes: AC107050.1, AC108865.1, AC108865.2, MRPS36P2, AC110772.1, AC110772.2, AC108046.1, LINC02374, AC097652.1, LINC02514, LINC02515, AC093763.2, AC093763.1.
- chr8:150,584–7,056,739, 110 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,234 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:4,136,644–117,539,464, 2,086 genes, copy number 5 (broad region; genes not listed).
- chr2:121,902,501–126,203,372, 22 genes, copy number 5 (within-gene range 4–5): AC011246.1, AC073632.1, AC062020.1, LINC01826, AC073409.2, AC073409.1, ELOAP1, PSMD14P1, AC064859.1, RN7SKP102, AC079154.1, CNTNAP5, MTND5P22, AC019159.2, AC019159.1, RNA5SP102, RNU6-259P, AC097499.2, LINC01889, AC097499.1, LINC01941, AC142116.2.
- chr2:142,131,178–152,099,167, 112 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:93,873,051–95,919,552, 16 genes, copy number 6 (within-gene range 2–6): PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC106719.1.
- chr3:114,314,500–115,147,288, 1 gene, copy number 6 (within-gene range 4–6): ZBTB20.
- chr3:114,445,521–198,222,513, 1,503 genes, copy number 5–6 (broad region; genes not listed).
- chr4:54,059,597–88,708,541, 563 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).
- chr7:17,374,867–17,680,659, 3 genes, copy number 6 (within-gene range 2–6): AC019117.2, AC019117.1, AC006482.1.
- chr7:52,165,235–57,837,046, 175 genes, copy number 35 (broad region; genes not listed).
- chr7:77,122,434–94,739,411, 200 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr7:96,858,182–109,999,624, 344 genes, copy number 5–7 (broad region; genes not listed).
- chr8:124,811,042–145,066,685, 378 genes, copy number 7 (broad region; genes not listed).
- chr10:34,109,560–34,815,325, 1 gene, copy number 5 (within-gene range 2–5): PARD3.
- chr10:34,488,583–36,089,389, 31 genes, copy number 5: ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, LINC02635, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5, LINC02630, AL355300.1.
- chr11:95,482,406–95,497,553, 1 gene, copy number 5: AP001790.1.
- chr12:66,767–38,329,721, 862 genes, copy number 7 (broad region; genes not listed).
- chr19:36,259,540–37,304,395, 40 genes, copy number 5 (within-gene range 3–5): LINC00665, AC092296.2, ZFP14, AC092296.1, AC092296.4, ZFP82, AC092296.3, ZNF566, AC092295.2, CTBP2P7, ZNF260, AC092295.1, ZNF529, ZNF529-AS1, ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2, ZNF790-AS1, ZNF790, ZNF345, Y_RNA, ZNF829, RPL31P61, ZNF568, ZNF420, AC010632.3, AC010632.1, AC010632.2, AC012309.1, ZNF585A, AC012309.2, ZNF585B, ZNF383, AC016590.1, LINC01535.
- chr20:87,250–38,033,461, 810 genes, copy number 6–10 (broad region; genes not listed).
- chr22:15,290,718–50,801,309, 1,376 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 246. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
